Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A8NS, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A8NS-01A (Primary Tumor).

[page 1 of 3]
ICD O-3
Adenocarcinoma NOS 8140/3
Site ^{C15.5} Esophagus, distal third
^{path} Esophagus, thoracic C15.1
Op 1/17/14

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

-year-old with heartburn, dysphagia and nocturnal food regurgitation. On
had esophageal biopsy which showed moderate to poorly differentiated
adenocarcinoma. On had barium swallow for achalasia with stricture of
distal esophageal narrowing to 8 mm over length of 2 cm.

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME: :
BIRTHDATE:

PATIENT NBR:

PAGE #: 2
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

1. "Thoracic esophagus" A 6.5 cm long segment of esophagus that has a 6.2 cm internal circumference. The proximal stomach measures 9.2 x 5.0 x 0.5 cm. The mucosa of the esophagus is gray-tan, finely folded. The mucosa of the stomach has a rugated, tan appearance that is remarkable for a 2.5 x 2.3 x 2.3 cm fungating tan-gray to pink tumor that has been previously incised by the surgeon. This tumor is located 2.1 cm away from the distal margin of resection. It partially involves the squamocolumnar junction. However, the tumor is found distal to the squamocolumnar junction. The tumor has a maximum depth of 1.3 cm and extends through to the adherent fibroadipose tissue. Upon sectioning the underlying tumor is 3.6 x 2.5 x 1.3 cm. One tongue of salmon-colored mucosa extending proximally from the squamocolumnar junction. Three possible lymph nodes are identified ranging up to 0.5 cm.
- 1A. Tumor to gastric margin.
1B-D. Tumor to deep.
1E. Tumor to squamocolumnar junction.
1F. Squamocolumnar junction.
1G. Three lymph nodes.
2. "Cervical esophageal margin." Tubular portion of tan-gray tissue consistent with esophagus, 1.9 cm in length and 2.3 cm in diameter. One aspect is stapled with the other aspect being open. The mucosa is tan-gray. No lesions are grossly noted.
- 2A. The opened margin.

PROCEDURE:

VERIFIED BY:

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Adenocarcinoma.

Arising in: Barrett's mucosa.

Depth of invasion: Adventitia.

Number of positive lymph nodes: 0.

Extranodal metastasis: Unknown.

Pattern of invasion: Infiltrative.

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 3
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

Esophageal and gastric resection margins involved: No.

Deep resection margin involved: No.

TNM classification: T3 NO MX.

PROCEDURE:

VERIFIED BY:

1. Esophagus and proximal stomach, resection: Transmurally invasive adenocarcinoma. Tumor arising in dysplastic intestinal metaplasia, presumably Barrett's mucosa. Three lymph nodes negative for carcinoma. Margins free. Perineurial invasion identified. Please see template.

2. Cervical esophagus, excision: Negative for Barrett's or neoplasm.

I, , the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Source: NCI Genomic Data Commons file 7e61a188-43a3-4e57-b4ff-15655b8ae4fb (TCGA-L5-A8NS.4FA8BFF8-A396-4E34-980D-622D41C20FE9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).